Gene-level copy-number profile of tumor specimen TCGA-DD-A119-01A from TCGA case TCGA-DD-A119, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 40.0 years (14,613 days).
Specimen TCGA-DD-A119-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.97fa8557-f258-4828-9956-2d62d0ab5714.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A119-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/931937ad-48c9-4690-b187-8aa28f5c21b9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 947; copy number 2: 4,792; copy number 3: 27,204; copy number 4: 19,559; copy number 5: 31; copy number 6: 5,684; copy number 7: 71; copy number 8: 202; copy number 10: 359; copy number 11: 422; copy number 12: 530; copy number 13: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A119-01A-11D-A12Y-01): tumor purity 0.75, ploidy 2.2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,603 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:215,376,484–218,541,899, 27 genes, copy number 7: VDAC1P10, AL450990.1, KCTD3, USH2A, SNORD116, AL358452.1, USH2A-AS2, USH2A-AS1, MRPS18BP1, ESRRG, GPATCH2, SPATA17, SPATA17-AS1, UBBP2, LINC00210, AL355526.1, LINC01653, AL355526.2, RNU1-141P, RRP15, AC096638.2, AC096638.1, TGFB2-AS1, TGFB2, TGFB2-OT1, LINC02869, U3.
- chr6:21,664,185–23,857,646, 16 genes, copy number 7 (within-gene range 6–7): CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1, AL133270.1, AL139093.1, SPTLC1P2.
- chr6:63,719,980–65,707,226, 1 gene, copy number 7 (within-gene range 6–7): EYS.
- chr6:64,377,795–69,389,506, 26 genes, copy number 7: AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1, ADGRB3.
- chr8:46,028,804–46,028,892, 1 gene, copy number 7: AC118650.1.
- chr8:46,579,213–145,066,685, 1,532 genes, copy number 8–13 (within-gene range 3–13) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 947. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
